Somatic mutation profile of tumor specimen C3L-02168-04 (aliquot CPT0175390006) from CPTAC case C3L-02168, project CPTAC-3 (Bronchus and lung — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage II; Tumor grade: G1; Age at diagnosis: 66.5 years (24,298 days).
Specimen C3L-02168-04: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0e62a5a9-43b0-4ff6-b11c-1db6353f4b06.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-02168-31 (Blood Derived Normal), aliquot CPT0175480002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f879955f-6794-4288-a306-f8fa90aff881

The open-access MAF lists 485 somatic variants for this specimen: 326 protein-altering or splice-affecting, 98 silent, 61 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 277, Silent 98, Intron 34, Nonsense Mutation 26, Frame Shift Del 9, RNA 9, 3'UTR 8, 5'UTR 7, Splice Site 6, Frame Shift Ins 3, 5'Flank 2, In Frame Del 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATM | c.4774G>T p.E1592* | Nonsense Mutation (SNP) | VAF 15/139 reads (11%) | catalogued as rs876658587, COSV53724585; ClinVar: pathogenic; called by muse, mutect2, varscan2
- LAMA2 | c.5476C>T p.R1826* | Nonsense Mutation (SNP) | VAF 92/419 reads (22%) | catalogued as rs747349942, CM983961, COSV70356540; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1624G>A p.E542K | Missense Mutation (SNP) | VAF 35/245 reads (14%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.912); catalogued as rs121913273, CM153078, COSV55873227, COSV55894248; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.743G>T p.R248L | Missense Mutation (SNP) | VAF 175/459 reads (38%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs11540652, CM920675, COSV52661091, COSV52661580, COSV52675468, COSV52802300; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TTR | c.272T>C p.V91A | Missense Mutation (SNP) | VAF 107/623 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as rs121918084, CM930709; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ACSM4 | c.178G>T p.D60Y | Missense Mutation (SNP) | VAF 107/446 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV68068229, COSV68069407; called by muse, mutect2, varscan2
- ADAMTS16 | c.3007G>A p.G1003R | Missense Mutation (SNP) | VAF 108/345 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56999920; called by muse, mutect2, varscan2
- ADCY3 | c.1139G>T p.R380L | Missense Mutation (SNP) | VAF 177/324 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.868); catalogued as COSV53166565; called by muse, mutect2, varscan2
- AMH | c.1457A>T p.N486I | Missense Mutation (SNP) | VAF 282/1050 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM147598; called by muse, mutect2, varscan2
- ANO4 | c.147C>A p.H49Q | Missense Mutation (SNP) | VAF 83/353 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.596); catalogued as rs1172926575; called by muse, mutect2, varscan2
- ATP6V0D2 | c.247G>T p.E83* | Nonsense Mutation (SNP) | VAF 20/126 reads (16%) | catalogued as rs755514597, COSV53414236; called by muse, mutect2, varscan2
- BMP7 | c.634G>T p.D212Y | Missense Mutation (SNP) | VAF 96/326 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs752403942; called by muse, mutect2, varscan2
- C11orf98 | c.83G>A p.R28Q | Missense Mutation (SNP) | VAF 75/470 reads (16%) | SIFT tolerated, low confidence (0.14); PolyPhen possibly damaging (0.773); catalogued as rs767806600; called by muse, mutect2, varscan2
- CASS4 | c.2189G>T p.R730L | Missense Mutation (SNP) | VAF 37/315 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV64387198; called by muse, mutect2, varscan2
- CBY2 | c.280C>A p.R94S | Missense Mutation (SNP) | VAF 109/404 reads (27%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.998); catalogued as COSV100137847; called by muse, mutect2, varscan2
- CD302 | c.67G>T p.D23Y | Missense Mutation (SNP) | VAF 64/441 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV52032996; called by muse, mutect2, varscan2
- CDH23 | c.8366G>A p.R2789Q | Missense Mutation (SNP) | VAF 42/260 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.011); catalogued as rs1473455187; called by muse, mutect2, varscan2
- CHST12 | c.628G>A p.A210T | Missense Mutation (SNP) | VAF 72/307 reads (23%) | SIFT tolerated (0.22); PolyPhen benign (0.007); catalogued as COSV99324509; called by muse, mutect2, varscan2
- CIAPIN1 | c.938A>G p.*313Wext*34 | Nonstop Mutation (SNP) | VAF 43/170 reads (25%) | catalogued as rs1314704965, COSV67953523; called by muse, mutect2, varscan2
- CLCN4 | c.2084G>T p.R695L | Missense Mutation (SNP) | VAF 218/440 reads (50%) | SIFT tolerated (0.13); PolyPhen benign (0.258); catalogued as COSV66465061; called by muse, mutect2, varscan2
- CLEC14A | c.1322C>A p.P441Q | Missense Mutation (SNP) | VAF 127/255 reads (50%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as rs1343788833, COSV100643516; called by muse, mutect2, varscan2
- CNTN6 | c.1325C>A p.S442Y | Missense Mutation (SNP) | VAF 127/275 reads (46%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.958); catalogued as COSV100610288; called by muse, mutect2, varscan2
- COG5 | c.410G>A p.R137K | Missense Mutation (SNP) | VAF 32/398 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.046); catalogued as COSV51746928; called by muse, mutect2
- COL19A1 | c.1732G>A p.E578K | Missense Mutation (SNP) | VAF 49/300 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.396); catalogued as rs1325807592; called by muse, mutect2, varscan2
- COL4A4 | c.1117G>T p.G373W | Missense Mutation (SNP) | VAF 110/290 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100306469; called by muse, mutect2, varscan2
- COPB1 | c.1526G>T p.G509V | Missense Mutation (SNP) | VAF 27/144 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as COSV51447447; called by muse, mutect2, varscan2
- COPE | c.324G>A p.M108I | Missense Mutation (SNP) | VAF 105/386 reads (27%) | SIFT tolerated (0.22); PolyPhen benign (0.005); catalogued as rs1310882485; called by muse, mutect2, varscan2
- CT47B1 | c.350C>A p.A117E | Missense Mutation (SNP) | VAF 241/480 reads (50%) | SIFT deleterious (0.03); PolyPhen benign (0.023); catalogued as COSV64891145; called by muse, mutect2, varscan2
- CTNND2 | c.1345C>A p.H449N | Missense Mutation (SNP) | VAF 89/269 reads (33%) | SIFT tolerated (0.18); PolyPhen benign (0.024); catalogued as COSV100481543; called by muse, mutect2, varscan2
- CXCL12 | c.200A>G p.N67S | Missense Mutation (SNP) | VAF 39/264 reads (15%) | SIFT tolerated (0.43); PolyPhen benign (0.006); catalogued as rs756265621; called by muse, mutect2, varscan2
- CYP2F1 | c.1192G>A p.D398N | Missense Mutation (SNP) | VAF 34/259 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs764980124; called by muse, mutect2, varscan2
- CZIB | c.230-1G>T p.X77_splice | Splice Site (SNP) | VAF 58/191 reads (30%) | catalogued as COSV53760137; called by muse, mutect2, varscan2
- DIO2 | c.157C>A p.R53S | Missense Mutation (SNP) | VAF 120/369 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs1265533572, COSV101375936; called by muse, mutect2, varscan2
- DNAH5 | c.953C>A p.A318E | Missense Mutation (SNP) | VAF 148/559 reads (26%) | SIFT tolerated (0.2); PolyPhen benign (0.334); catalogued as COSV54219545; called by muse, mutect2, varscan2
- DOP1B | c.3121G>T p.A1041S | Missense Mutation (SNP) | VAF 40/119 reads (34%) | SIFT tolerated (0.6); PolyPhen benign (0.017); catalogued as rs762571576, COSV67694477; called by muse, mutect2, varscan2
- DRP2 | c.1402G>A p.V468M | Missense Mutation (SNP) | VAF 58/276 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.933); catalogued as rs1315075734; called by muse, mutect2, varscan2
- ELMOD1 | c.868G>T p.E290* | Nonsense Mutation (SNP) | VAF 28/142 reads (20%) | catalogued as COSV56190587, COSV56191859; called by muse, mutect2, varscan2
- ENTPD1 | c.1342G>A p.A448T | Missense Mutation (SNP) | VAF 83/530 reads (16%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.951); catalogued as rs768179232, COSV100967583; called by muse, mutect2, varscan2
- EP400 | c.4202G>T p.R1401L | Missense Mutation (SNP) | VAF 25/177 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.22); catalogued as COSV100201801; called by muse, mutect2, varscan2
- ESPNL | c.2719G>A p.E907K | Missense Mutation (SNP) | VAF 160/328 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as rs573941455; called by muse, mutect2, varscan2
- F9 | c.1343C>G p.S448C | Missense Mutation (SNP) | VAF 39/70 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as CD930979, CM045149, CM940738, COSV54380220; called by muse, mutect2, varscan2
- FAM71E2 | c.2468C>A p.P823Q | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV100427794; called by muse, mutect2, varscan2
- FKBP6 | c.244C>T p.R82W | Missense Mutation (SNP) | VAF 94/521 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.892); catalogued as rs782794976, COSV52719619; called by muse, mutect2, varscan2
- FPR1 | c.281G>T p.G94V | Missense Mutation (SNP) | VAF 76/381 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59052992; called by muse, mutect2, varscan2
- FPR1 | c.280G>T p.G94C | Missense Mutation (SNP) | VAF 74/380 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59051571; called by muse, mutect2, varscan2
- GABRG1 | c.1127C>A p.A376D | Missense Mutation (SNP) | VAF 23/89 reads (26%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs200059897, COSV99778667; called by muse, mutect2, varscan2
- GAREM1 | c.1240G>T p.A414S | Missense Mutation (SNP) | VAF 74/455 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs775277452; called by muse, mutect2, varscan2
- GAREM2 | c.614G>A p.G205D | Missense Mutation (SNP) | VAF 281/463 reads (61%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.062); catalogued as rs1327898048; called by muse, mutect2, varscan2
- GJC2 | c.130G>A p.E44K | Missense Mutation (SNP) | VAF 66/564 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV64513098; called by muse, mutect2, varscan2
- GLIS2 | c.1037C>T p.P346L | Missense Mutation (SNP) | VAF 32/265 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as rs978655165; called by muse, mutect2, varscan2
- GPR6 | c.145G>C p.G49R | Missense Mutation (SNP) | VAF 121/614 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV51573866; called by muse, mutect2, varscan2
- GXYLT1 | c.19G>C p.V7L | Missense Mutation (SNP) | VAF 12/314 reads (4%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.003); catalogued as COSV55136830; called by muse, mutect2
- H1-6 | c.120del p.N41Tfs*7 | Frame Shift Del (DEL) | VAF 61/518 reads (12%) | catalogued as rs1194684497; called by mutect2, pindel, varscan2
- HOXC11 | c.368G>A p.G123D | Missense Mutation (SNP) | VAF 88/380 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.09); catalogued as rs769147038, COSV54534135; called by muse, varscan2
- ITGBL1 | c.888C>A p.C296* | Nonsense Mutation (SNP) | VAF 35/214 reads (16%) | catalogued as rs141099808; called by muse, mutect2, varscan2
- JAK3 | c.40C>A p.R14S | Missense Mutation (SNP) | VAF 67/374 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV71688281; called by muse, mutect2, varscan2
- KCNC2 | c.680C>A p.A227D | Missense Mutation (SNP) | VAF 77/306 reads (25%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.573); catalogued as COSV54363675; called by muse, mutect2, varscan2
- KIRREL3 | c.410G>T p.R137L | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV73107765; called by muse, mutect2
- LHCGR | c.364C>T p.L122F | Missense Mutation (SNP) | VAF 107/390 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.062); catalogued as COSV54295346; called by muse, mutect2, varscan2
- LRRC9 | c.3782G>A p.R1261Q | Missense Mutation (SNP) | VAF 48/157 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.613); catalogued as rs898226716, COSV99579524; called by muse, mutect2, varscan2
- MALRD1 | c.2078G>A p.R693Q | Missense Mutation (SNP) | VAF 62/254 reads (24%) | SIFT tolerated (0.62); PolyPhen benign (0.009); catalogued as rs550917010; called by muse, mutect2, varscan2
- MKRN3 | c.892G>T p.E298* | Nonsense Mutation (SNP) | VAF 38/233 reads (16%) | catalogued as COSV58809475; called by mutect2, varscan2
- MUC17 | c.2083G>A p.V695I | Missense Mutation (SNP) | VAF 92/280 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.013); catalogued as rs1351318192; called by muse, mutect2, varscan2
- MYH13 | c.1141G>A p.E381K | Missense Mutation (SNP) | VAF 41/97 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.784); catalogued as rs760092709, COSV99355533; called by muse, mutect2, varscan2
- MYO10 | c.3724C>A p.R1242S | Missense Mutation (SNP) | VAF 97/716 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57018240; called by muse, mutect2, varscan2
- NCAM2 | c.1483G>A p.V495M | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.593); catalogued as COSV53108831; called by muse, mutect2
- NLRP2 | c.1943G>A p.R648Q | Missense Mutation (SNP) | VAF 26/574 reads (5%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs753846462; called by muse, mutect2
- NUP107 | c.2635G>A p.D879N | Missense Mutation (SNP) | VAF 16/96 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.054); catalogued as COSV57497920; called by muse, mutect2, varscan2
- OR2J3 | c.609G>T p.M203I | Missense Mutation (SNP) | VAF 49/364 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.012); catalogued as COSV65849602; called by muse, mutect2, varscan2
- OR51B6 | c.349G>T p.A117S | Missense Mutation (SNP) | VAF 27/202 reads (13%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.45); catalogued as COSV66512823; called by muse, mutect2
- OR52K1 | c.360G>A p.M120I | Missense Mutation (SNP) | VAF 70/278 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs147098497; called by muse, mutect2, varscan2
- PASD1 | c.1123G>T p.E375* | Nonsense Mutation (SNP) | VAF 74/158 reads (47%) | catalogued as COSV64854218, COSV64854680; called by muse, mutect2, varscan2
- PCDH10 | c.2413G>C p.E805Q | Missense Mutation (SNP) | VAF 38/286 reads (13%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.986); catalogued as COSV99993582; called by muse, mutect2, varscan2
- PCDH8 | c.1052C>A p.A351E | Missense Mutation (SNP) | VAF 16/108 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as COSV58813795; called by muse, varscan2
- PDE7B | c.861G>C p.Q287H | Missense Mutation (SNP) | VAF 31/251 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV57497000; called by muse, mutect2, varscan2
- PGBD1 | c.2078G>A p.G693D | Missense Mutation (SNP) | VAF 67/265 reads (25%) | SIFT tolerated (0.24); PolyPhen benign (0.005); catalogued as rs1181275574, COSV52554026; called by muse, mutect2, varscan2
- PHKG1 | c.80del p.G27Afs*22 | Frame Shift Del (DEL) | VAF 66/286 reads (23%) | catalogued as COSV99818110; called by mutect2, pindel, varscan2
- PIK3R1 | c.1382G>A p.R461Q (on ENST00000521381 / NM_181523.3; = p.R191Q on NM_181504.4) | Missense Mutation (SNP) | VAF 24/149 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.025); catalogued as COSV99073770; called by muse, mutect2, varscan2
- PLSCR2 | c.865-1G>T p.X289_splice (on ENST00000497985 / NM_001199978.1; = p.X216_splice on NM_020359.2) | Splice Site (SNP) | VAF 98/188 reads (52%) | catalogued as COSV100367809; called by muse, mutect2, varscan2
- PNLIPRP1 | c.685C>A p.P229T | Missense Mutation (SNP) | VAF 22/139 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); catalogued as COSV62610845; called by muse, mutect2, varscan2
- PPP1R3F | c.555C>G p.H185Q | Missense Mutation (SNP) | VAF 181/351 reads (52%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.89); catalogued as COSV99279126; called by muse, mutect2, varscan2
- PRDM9 | c.697G>T p.G233W | Missense Mutation (SNP) | VAF 224/948 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV57004159, COSV99691416; called by muse, mutect2, varscan2
- PROKR2 | c.404G>A p.R135H | Missense Mutation (SNP) | VAF 34/264 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs746638938, COSV54085675; called by muse, mutect2, varscan2
- PSAPL1 | c.1151C>T p.S384F | Missense Mutation (SNP) | VAF 50/218 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.615); catalogued as COSV100040265; called by mutect2, varscan2
- RABEP2 | c.1037G>A p.R346Q | Missense Mutation (SNP) | VAF 20/323 reads (6%) | SIFT tolerated (0.88); PolyPhen benign (0.007); catalogued as rs767327883, COSV62868647; called by muse, mutect2
- RBFOX1 | c.955G>A p.A319T | Missense Mutation (SNP) | VAF 39/266 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.325); catalogued as rs199644500, COSV100300321, COSV60951913; called by muse, mutect2, varscan2
- RGS7BP | c.694C>A p.L232I | Missense Mutation (SNP) | VAF 81/275 reads (29%) | SIFT tolerated, low confidence (0.14); PolyPhen probably damaging (0.978); catalogued as COSV100470236; called by muse, mutect2, varscan2
- RNF6 | c.1660G>A p.E554K | Missense Mutation (SNP) | VAF 56/186 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.058); catalogued as rs1421398633, COSV60418882; called by muse, mutect2, varscan2
- SCN4A | c.904G>A p.G302S | Missense Mutation (SNP) | VAF 153/719 reads (21%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0.003); catalogued as rs756852107, COSV101438326; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SEMG2 | c.622C>A p.R208S | Missense Mutation (SNP) | VAF 76/213 reads (36%) | SIFT tolerated (0.14); PolyPhen benign (0.154); catalogued as COSV65647631; called by muse, mutect2, varscan2
- SIM1 | c.1444C>A p.P482T | Missense Mutation (SNP) | VAF 55/298 reads (18%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.953); catalogued as COSV53489191; called by muse, mutect2, varscan2
- SLC17A6 | c.358G>T p.D120Y | Missense Mutation (SNP) | VAF 69/297 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV54138958; called by muse, mutect2, varscan2
- SLCO1B1 | c.1551C>A p.Y517* | Nonsense Mutation (SNP) | VAF 116/468 reads (25%) | catalogued as COSV57009337; called by muse, mutect2, varscan2
- SORCS1 | c.2802G>C p.L934F | Missense Mutation (SNP) | VAF 13/112 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.033); catalogued as COSV53840639; called by muse, mutect2, varscan2
- STAT5B | c.1669C>A p.Q557K | Missense Mutation (SNP) | VAF 97/725 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.55); catalogued as COSV53182923; called by muse, mutect2, varscan2
- STYXL2 | c.1069G>T p.G357W | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.533); catalogued as COSV54802954; called by muse, mutect2, varscan2
- SYNE1 | c.7064A>G p.N2355S (on ENST00000367255 / NM_182961.4; = p.N2362S on NM_033071.3) | Missense Mutation (SNP) | VAF 80/421 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs377180714; called by muse, mutect2, varscan2
- TAAR2 | c.422G>T p.R141I (on ENST00000367931 / NM_001033080.1; = p.R96I on NM_014626.3) | Missense Mutation (SNP) | VAF 30/194 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51579591; called by muse, mutect2, varscan2
- TAFA2 | c.215G>T p.G72V | Missense Mutation (SNP) | VAF 81/292 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101352804, COSV69171784; called by muse, mutect2, varscan2
- TBX5 | c.205G>A p.E69K | Missense Mutation (SNP) | VAF 150/642 reads (23%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as CM971436, COSV59858590; called by muse, mutect2, varscan2
- TMEM130 | c.1240G>T p.E414* (on ENST00000416379 / NM_001134450.2; = p.E402* on NM_152913.3) | Nonsense Mutation (SNP) | VAF 67/412 reads (16%) | catalogued as COSV59559377, COSV59561315; called by muse, mutect2, varscan2
- TRIM60 | c.985G>A p.D329N | Missense Mutation (SNP) | VAF 36/118 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV61970398; called by muse, varscan2
- TSKS | c.1527C>A p.H509Q | Missense Mutation (SNP) | VAF 70/289 reads (24%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.995); catalogued as COSV99882934; called by muse, mutect2, varscan2
- WWOX | c.449A>T p.H150L | Missense Mutation (SNP) | VAF 99/475 reads (21%) | SIFT tolerated (0.35); PolyPhen benign (0.006); catalogued as rs745453076; called by muse, mutect2, varscan2
- XKR5 | c.641C>T p.A214V | Missense Mutation (SNP) | VAF 33/106 reads (31%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.955); catalogued as rs765312421; called by muse, mutect2, varscan2
- ZGRF1 | c.3218G>A p.R1073H | Missense Mutation (SNP) | VAF 48/129 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.169); catalogued as rs932972323; called by muse, mutect2, varscan2
- ZNF207 | c.815C>T p.S272L | Missense Mutation (SNP) | VAF 39/260 reads (15%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as COSV58301274; called by muse, mutect2, varscan2
- ZNF552 | c.49G>A p.E17K | Missense Mutation (SNP) | VAF 46/220 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.941); catalogued as rs1394308366; called by muse, mutect2, varscan2
- ZNF620 | c.20G>T p.R7L | Missense Mutation (SNP) | VAF 167/499 reads (33%) | SIFT tolerated (0.78); PolyPhen benign (0.019); catalogued as COSV100093945, COSV58820377; called by muse, mutect2, varscan2
- ZSCAN5C | c.85C>T p.P29S | Missense Mutation (SNP) | VAF 35/153 reads (23%) | SIFT tolerated (0.41); PolyPhen benign (0.015); catalogued as rs570960186; called by muse, mutect2, varscan2
- ZWINT | c.761C>A p.T254N | Missense Mutation (SNP) | VAF 21/165 reads (13%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.007); catalogued as COSV59186130; called by muse, mutect2, varscan2
- ABCA8 | c.1350C>A p.H450Q | Missense Mutation (SNP) | VAF 72/285 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- ACSF3 | c.1387G>T p.D463Y | Missense Mutation (SNP) | VAF 81/544 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); called by muse, mutect2, varscan2
- ADAD2 | c.1151C>A p.P384H (on ENST00000315906 / NM_001145400.2; = p.P466H on NM_139174.4) | Missense Mutation (SNP) | VAF 63/365 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.28); called by muse, mutect2, varscan2
- ADAM18 | c.1894G>T p.G632W | Missense Mutation (SNP) | VAF 34/139 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ADAMTS6 | c.214A>T p.S72C | Missense Mutation (SNP) | VAF 49/152 reads (32%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.937); called by muse, mutect2, varscan2
- ADGB | c.1916G>C p.C639S | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.345); called by muse, mutect2, varscan2
- ADGRB3 | c.3187G>C p.G1063R | Missense Mutation (SNP) | VAF 18/109 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); called by muse, mutect2, varscan2
- ADGRG4 | c.5707A>G p.T1903A | Missense Mutation (SNP) | VAF 22/95 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- AKAP7 | c.579G>T p.L193F | Missense Mutation (SNP) | VAF 54/287 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.123); called by muse, mutect2, varscan2
- AL163540.1 | n.60+1G>T | Splice Site (SNP) | VAF 35/355 reads (10%) | called by muse, mutect2, varscan2
- ALOX5 | c.1386C>A p.S462R | Missense Mutation (SNP) | VAF 36/262 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- ANHX | c.871G>A p.G291S | Missense Mutation (SNP) | VAF 103/418 reads (25%) | SIFT tolerated (0.26); PolyPhen benign (0.19); called by muse, mutect2, varscan2
- ANKRD30B | c.163G>T p.E55* | Nonsense Mutation (SNP) | VAF 29/156 reads (19%) | called by muse, mutect2, varscan2
- ANXA2R | c.464C>G p.P155R | Missense Mutation (SNP) | VAF 26/270 reads (10%) | SIFT tolerated (0.65); PolyPhen benign (0); called by muse, mutect2
- APLNR | c.780C>A p.C260* | Nonsense Mutation (SNP) | VAF 31/140 reads (22%) | called by muse, mutect2, varscan2
- APOA1 | c.20C>T p.T7I | Missense Mutation (SNP) | VAF 89/454 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.097); called by muse, mutect2, varscan2
- ARHGAP28 | c.248G>C p.R83P | Missense Mutation (SNP) | VAF 45/258 reads (17%) | SIFT tolerated (0.19); PolyPhen benign (0.222); called by muse, mutect2, varscan2
- ARPP19 | c.115C>A p.L39M | Missense Mutation (SNP) | VAF 30/259 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.876); called by muse, mutect2, varscan2
- ASH2L | c.1201G>A p.V401M | Missense Mutation (SNP) | VAF 88/525 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ASTE1 | c.979G>A p.E327K | Missense Mutation (SNP) | VAF 119/592 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- ATP6V1B2 | c.556G>T p.G186W | Missense Mutation (SNP) | VAF 66/242 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AUTS2 | c.2683A>G p.R895G | Missense Mutation (SNP) | VAF 89/461 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- AZU1 | c.70C>A p.L24I | Missense Mutation (SNP) | VAF 53/170 reads (31%) | SIFT tolerated (0.4); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- BEST3 | c.878A>T p.Q293L | Missense Mutation (SNP) | VAF 33/150 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.679); called by muse, mutect2, varscan2
- BRAF | c.1475T>A p.I492N (on ENST00000288602 / NM_001374244.1; = p.I452N on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 181/471 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- BRINP3 | c.1749C>A p.S583R | Missense Mutation (SNP) | VAF 47/220 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- C18orf63 | c.715T>C p.Y239H | Missense Mutation (SNP) | VAF 27/152 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- C8orf58 | c.770C>A p.A257E | Missense Mutation (SNP) | VAF 22/170 reads (13%) | SIFT tolerated (0.22); PolyPhen benign (0.015); called by muse, varscan2
- CACNA1H | c.169G>C p.E57Q | Missense Mutation (SNP) | VAF 141/510 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- CACNG1 | c.495G>C p.M165I | Missense Mutation (SNP) | VAF 59/457 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.228); called by muse, mutect2, varscan2
- CACNG8 | c.1232C>A p.A411D | Missense Mutation (SNP) | VAF 65/271 reads (24%) | SIFT tolerated, low confidence (0.65); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- CALR | c.568C>T p.Q190* | Nonsense Mutation (SNP) | VAF 61/551 reads (11%) | called by muse, mutect2, varscan2
- CASD1 | c.192del p.W64Cfs*7 | Frame Shift Del (DEL) | VAF 13/96 reads (14%) | called by mutect2, pindel, varscan2
- CCDC3 | c.97G>A p.E33K | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.669); called by muse, mutect2, varscan2
- CCN3 | c.217G>A p.E73K | Missense Mutation (SNP) | VAF 168/600 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.508); called by muse, mutect2, varscan2
- CCT8L2 | c.1318G>T p.A440S | Missense Mutation (SNP) | VAF 105/467 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.823); called by muse, mutect2, varscan2
- CD2BP2 | c.184A>T p.K62* | Nonsense Mutation (SNP) | VAF 12/234 reads (5%) | called by muse, mutect2
- CDC14A | c.2T>A p.M1? | Translation Start Site (SNP) | VAF 92/265 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.188); called by muse, mutect2, varscan2
- CDH10 | c.768C>A p.N256K | Missense Mutation (SNP) | VAF 80/292 reads (27%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.595); called by muse, varscan2
- CDK13 | c.2516_2530del p.K839_L844delinsI | In Frame Del (DEL) | VAF 14/100 reads (14%) | called by mutect2, pindel
- CDKN2A | c.46_57del p.L16_A19del | In Frame Del (DEL) | VAF 57/318 reads (18%) | called by mutect2, pindel, varscan2
- CELSR1 | c.6565C>A p.H2189N | Missense Mutation (SNP) | VAF 97/467 reads (21%) | SIFT tolerated (0.2); PolyPhen benign (0.247); called by muse, mutect2, varscan2
- CERS1 | c.25G>T p.G9W | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.318); called by muse, mutect2
- CFAP47 | c.1539T>A p.Y513* | Nonsense Mutation (SNP) | VAF 17/44 reads (39%) | called by muse, mutect2, varscan2
- CFAP91 | c.1639del p.T547Pfs*30 | Frame Shift Del (DEL) | VAF 132/839 reads (16%) | called by mutect2, pindel, varscan2
- CHIA | c.142C>A p.P48T | Missense Mutation (SNP) | VAF 152/544 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by mutect2, varscan2
- CHRNA3 | c.1106C>T p.P369L | Missense Mutation (SNP) | VAF 46/549 reads (8%) | SIFT tolerated (0.31); PolyPhen benign (0.067); called by muse, mutect2
- CNTN6 | c.1012G>A p.E338K | Missense Mutation (SNP) | VAF 19/280 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2
- COL6A1 | c.523G>T p.A175S | Missense Mutation (SNP) | VAF 78/240 reads (33%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CPAMD8 | c.936G>C p.M312I (on ENST00000651564; = p.M265I on NM_015692.5) | Missense Mutation (SNP) | VAF 70/285 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- CPSF2 | c.976G>C p.V326L | Missense Mutation (SNP) | VAF 125/333 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- CRACD | c.836C>A p.P279Q | Missense Mutation (SNP) | VAF 47/261 reads (18%) | SIFT tolerated (0.39); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CRB1 | c.2901del p.N968Ifs*20 | Frame Shift Del (DEL) | VAF 51/192 reads (27%) | called by mutect2, pindel, varscan2
- CTIF | c.4G>T p.E2* | Nonsense Mutation (SNP) | VAF 11/64 reads (17%) | called by muse, mutect2, varscan2
- CTNNA3 | c.2486C>G p.S829* | Nonsense Mutation (SNP) | VAF 64/350 reads (18%) | called by muse, mutect2, varscan2
- CXorf66 | c.322G>T p.E108* | Nonsense Mutation (SNP) | VAF 55/114 reads (48%) | called by muse, mutect2, varscan2
- DCAF8L2 | c.667C>G p.R223G | Missense Mutation (SNP) | VAF 91/183 reads (50%) | SIFT tolerated (0.72); PolyPhen benign (0); called by muse, mutect2, varscan2
- DERPC | c.175G>T p.G59C | Missense Mutation (SNP) | VAF 38/270 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DOK4 | c.747C>A p.N249K | Missense Mutation (SNP) | VAF 22/90 reads (24%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.055); called by muse, mutect2
- ECPAS | c.1789C>T p.L597F | Missense Mutation (SNP) | VAF 50/190 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- EIF2AK4 | c.4885G>C p.E1629Q | Missense Mutation (SNP) | VAF 20/151 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.357); called by muse, mutect2, varscan2
- EPG5 | c.5527G>A p.E1843K | Missense Mutation (SNP) | VAF 49/161 reads (30%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.461); called by muse, mutect2, varscan2
- ERMAP | c.836T>A p.V279D | Missense Mutation (SNP) | VAF 179/526 reads (34%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ERN2 | c.711G>T p.Q237H | Missense Mutation (SNP) | VAF 73/638 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- FASTK | c.312G>C p.Q104H | Missense Mutation (SNP) | VAF 94/636 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.671); called by muse, mutect2, varscan2
- FAT3 | c.3362C>T p.T1121I | Missense Mutation (SNP) | VAF 36/244 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.474); called by muse, mutect2, varscan2
- FBXO11 | c.2762C>G p.S921C (on ENST00000403359 / NM_001190274.2; = p.S837C on NM_025133.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 118/226 reads (52%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- FGF10 | c.410A>T p.K137M | Missense Mutation (SNP) | VAF 150/667 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.718); called by muse, mutect2, varscan2
- FLG | c.3341C>T p.S1114L | Missense Mutation (SNP) | VAF 101/823 reads (12%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- FLG2 | c.6763C>A p.H2255N | Missense Mutation (SNP) | VAF 122/565 reads (22%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- FN1 | c.5517G>C p.E1839D | Missense Mutation (SNP) | VAF 72/510 reads (14%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- FRG1 | c.140G>T p.W47L | Missense Mutation (SNP) | VAF 22/73 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- GABRG2 | c.213C>A p.N71K | Missense Mutation (SNP) | VAF 107/327 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- GABRG2 | c.566A>T p.E189V | Missense Mutation (SNP) | VAF 59/230 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- GABRR1 | c.54G>T p.W18C | Missense Mutation (SNP) | VAF 88/416 reads (21%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); called by muse, mutect2, varscan2
- GAS2 | c.803C>A p.P268H | Missense Mutation (SNP) | VAF 72/561 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GATA5 | c.738C>A p.C246* | Nonsense Mutation (SNP) | VAF 99/417 reads (24%) | called by muse, mutect2, varscan2
- GLYATL3 | c.598C>A p.P200T | Missense Mutation (SNP) | VAF 91/592 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GOT1L1 | c.1075C>G p.Q359E | Missense Mutation (SNP) | VAF 31/82 reads (38%) | SIFT tolerated (0.18); PolyPhen benign (0.005); called by muse, varscan2
- GPR149 | c.785G>T p.R262L | Missense Mutation (SNP) | VAF 79/365 reads (22%) | SIFT tolerated (0.17); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- GRID1 | c.2152G>A p.A718T | Missense Mutation (SNP) | VAF 53/225 reads (24%) | SIFT tolerated (0.3); PolyPhen benign (0.098); called by muse, mutect2, varscan2
- GRIK3 | c.1861C>A p.L621M | Missense Mutation (SNP) | VAF 57/171 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GYS2 | c.1773G>T p.R591S | Missense Mutation (SNP) | VAF 75/307 reads (24%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- HMCN2 | c.15173C>T p.P5058L | Missense Mutation (SNP) | VAF 46/161 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HMGXB3 | c.2091G>T p.E697D (on ENST00000613459; = p.E451D on NM_014983.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 94/261 reads (36%) | SIFT tolerated (0.2); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- HSPA12A | c.1496G>T p.G499V | Missense Mutation (SNP) | VAF 35/282 reads (12%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.887); called by muse, mutect2, varscan2
- HTR4 | c.25A>T p.S9C | Missense Mutation (SNP) | VAF 33/105 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.315); called by muse, mutect2, varscan2
- IGFALS | c.554T>C p.L185P | Missense Mutation (SNP) | VAF 166/623 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IGKV2D-30 | c.175A>G p.N59D | Missense Mutation (SNP) | VAF 42/472 reads (9%) | SIFT tolerated (0.41); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ING1 | c.170T>G p.F57C | Missense Mutation (SNP) | VAF 16/140 reads (11%) | SIFT tolerated, low confidence (0.14); PolyPhen possibly damaging (0.785); called by muse, mutect2, varscan2
- KCNK18 | c.259C>A p.L87M | Missense Mutation (SNP) | VAF 67/487 reads (14%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- KIF24 | c.3533A>C p.E1178A | Missense Mutation (SNP) | VAF 34/301 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- KLHL41 | c.952G>A p.D318N | Missense Mutation (SNP) | VAF 57/393 reads (15%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.615); called by muse, mutect2, varscan2
- KNTC1 | c.2487-1G>T p.X829_splice | Splice Site (SNP) | VAF 25/78 reads (32%) | called by muse, mutect2, varscan2
- LATS2 | c.3241G>A p.E1081K | Missense Mutation (SNP) | VAF 40/124 reads (32%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.212); called by muse, varscan2
- LRP1B | c.10341G>T p.K3447N | Missense Mutation (SNP) | VAF 113/324 reads (35%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.874); called by muse, mutect2, varscan2
- LRRC31 | c.1394T>A p.I465N | Missense Mutation (SNP) | VAF 129/615 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); called by muse, mutect2, varscan2
- LRRC7 | c.2122T>C p.S708P (on ENST00000651989 / NM_001370785.2; = p.S675P on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 30/102 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.748); called by muse, mutect2
- LRRN1 | c.160A>G p.T54A | Missense Mutation (SNP) | VAF 221/379 reads (58%) | SIFT tolerated (0.84); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- LRRTM4 | c.538T>A p.C180S | Missense Mutation (SNP) | VAF 155/273 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MAMLD1 | c.150C>A p.S50R | Missense Mutation (SNP) | VAF 54/318 reads (17%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- MBOAT4 | c.915G>C p.K305N | Missense Mutation (SNP) | VAF 52/391 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- MEAK7 | c.240G>T p.K80N | Missense Mutation (SNP) | VAF 77/536 reads (14%) | SIFT tolerated (0.48); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- MED23 | c.3943G>A p.E1315K | Missense Mutation (SNP) | VAF 48/237 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.598); called by muse, mutect2, varscan2
- MEP1A | c.2068G>T p.G690W | Missense Mutation (SNP) | VAF 121/542 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MFAP1 | c.799A>G p.T267A | Missense Mutation (SNP) | VAF 76/272 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- MGAM2 | c.6043G>T p.A2015S | Missense Mutation (SNP) | VAF 38/309 reads (12%) | SIFT tolerated, low confidence (0.67); called by muse, mutect2, varscan2
- MMACHC | c.366T>A p.H122Q | Missense Mutation (SNP) | VAF 76/246 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MON1B | c.115C>T p.P39S | Missense Mutation (SNP) | VAF 33/189 reads (17%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- MRGPRX4 | c.960G>T p.L320F | Missense Mutation (SNP) | VAF 14/92 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- MROH2B | c.3884T>C p.L1295P | Missense Mutation (SNP) | VAF 87/286 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MTTP | c.1291A>C p.I431L | Missense Mutation (SNP) | VAF 85/230 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- MUC16 | c.3946G>T p.G1316C | Missense Mutation (SNP) | VAF 54/186 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.184); called by muse, mutect2, varscan2
- MUC5B | c.15898G>T p.A5300S | Missense Mutation (SNP) | VAF 26/100 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.212); called by muse, mutect2, varscan2
- MYEOV | c.361C>A p.L121I | Missense Mutation (SNP) | VAF 66/390 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- MYH15 | c.1325C>A p.S442* | Nonsense Mutation (SNP) | VAF 24/315 reads (8%) | called by muse, mutect2
- NAALAD2 | c.1302G>T p.E434D | Missense Mutation (SNP) | VAF 26/131 reads (20%) | SIFT tolerated (0.17); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NLGN3 | c.1780T>C p.S594P (on ENST00000358741 / NM_181303.2; = p.S574P on NM_018977.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 116/214 reads (54%) | SIFT tolerated (0.46); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- NOBOX | c.1470C>A p.S490R | Missense Mutation (SNP) | VAF 16/187 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.163); called by muse, mutect2
- NOP56 | c.1511C>G p.S504C | Missense Mutation (SNP) | VAF 47/124 reads (38%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.174); called by muse, mutect2, varscan2
- NRXN1 | c.161T>G p.M54R | Missense Mutation (SNP) | VAF 86/161 reads (53%) | SIFT deleterious (0); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- NUCB2 | c.144A>G p.P48= | Splice Region (SNP) | VAF 58/247 reads (23%) | called by muse, mutect2, varscan2
- NUP107 | c.1996G>A p.E666K | Missense Mutation (SNP) | VAF 22/270 reads (8%) | SIFT tolerated (0.55); PolyPhen benign (0.01); called by muse, mutect2
- OR10G9 | c.874A>T p.K292* | Nonsense Mutation (SNP) | VAF 29/140 reads (21%) | called by muse, mutect2, varscan2
- OR11L1 | c.499G>T p.D167Y | Missense Mutation (SNP) | VAF 101/364 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.288); called by muse, mutect2, varscan2
- OR13A1 | c.470T>A p.V157E | Missense Mutation (SNP) | VAF 27/169 reads (16%) | SIFT tolerated (0.57); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR14I1 | c.797C>T p.S266F | Missense Mutation (SNP) | VAF 26/195 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- OR2T1 | c.912G>C p.L304F | Missense Mutation (SNP) | VAF 30/146 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.029); called by muse, varscan2
- OR2T35 | c.796C>A p.H266N | Missense Mutation (SNP) | VAF 83/463 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR4K1 | c.835A>T p.T279S | Missense Mutation (SNP) | VAF 48/316 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- OR4M1 | c.331dup p.E111Gfs*11 | Frame Shift Ins (INS) | VAF 159/1199 reads (13%) | called by mutect2, pindel, varscan2
- OR4N2 | c.761G>T p.G254V | Missense Mutation (SNP) | VAF 275/1408 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.155); called by muse, mutect2, varscan2
- OR6C65 | c.245A>G p.N82S | Missense Mutation (SNP) | VAF 38/141 reads (27%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- OR6M1 | c.142T>A p.W48R | Missense Mutation (SNP) | VAF 34/261 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR8G1 | c.392T>A p.L131Q | Missense Mutation (SNP) | VAF 52/202 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.459); called by muse, mutect2, varscan2
- OR8U1 | c.62A>T p.Q21L | Missense Mutation (SNP) | VAF 30/133 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0); called by muse, mutect2
- PBRM1 | c.1660G>C p.D554H | Missense Mutation (SNP) | VAF 38/213 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- PCDH17 | c.1846G>T p.D616Y | Missense Mutation (SNP) | VAF 72/470 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PCDH9 | c.2884C>G p.H962D | Missense Mutation (SNP) | VAF 34/251 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PCDHB5 | c.1496T>A p.L499H | Missense Mutation (SNP) | VAF 290/855 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PCLO | c.2756A>T p.Q919L | Missense Mutation (SNP) | VAF 67/183 reads (37%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.852); called by muse, mutect2, varscan2
- PDILT | c.1538A>C p.E513A | Missense Mutation (SNP) | VAF 74/231 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- PENK | c.511C>A p.H171N | Missense Mutation (SNP) | VAF 105/433 reads (24%) | SIFT tolerated (0.55); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- PHF20L1 | c.1127A>G p.Q376R | Missense Mutation (SNP) | VAF 48/170 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- PIWIL2 | c.1759A>G p.N587D | Missense Mutation (SNP) | VAF 23/126 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- PLA2G4C | c.56C>G p.A19G | Missense Mutation (SNP) | VAF 70/303 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.236); called by muse, mutect2, varscan2
- PLBD2 | c.563A>C p.Q188P | Missense Mutation (SNP) | VAF 70/281 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PLCG2 | c.1072+1G>T p.X358_splice | Splice Site (SNP) | VAF 55/248 reads (22%) | called by muse, mutect2, varscan2
- PLCXD3 | c.640G>A p.A214T | Missense Mutation (SNP) | VAF 43/330 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- POGK | c.358+1G>A p.X120_splice | Splice Site (SNP) | VAF 15/103 reads (15%) | called by muse, mutect2, varscan2
- PRELID2 | c.178C>T p.Q60* (on ENST00000334744 / NM_182960.4; = p.Q31* on NM_138492.6) | Nonsense Mutation (SNP) | VAF 53/175 reads (30%) | called by muse, mutect2, varscan2
- PRPF31 | c.894G>C p.K298N | Missense Mutation (SNP) | VAF 32/886 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PTCHD3 | c.1961G>C p.G654A | Missense Mutation (SNP) | VAF 57/246 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PTGIR | c.529del p.A177Pfs*62 | Frame Shift Del (DEL) | VAF 68/264 reads (26%) | called by mutect2, pindel, varscan2
- PXDNL | c.3479G>T p.C1160F | Missense Mutation (SNP) | VAF 26/208 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PXDNL | c.2770T>A p.F924I | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- RB1CC1 | c.629G>T p.R210I | Missense Mutation (SNP) | VAF 40/148 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); called by muse, mutect2
- RBMXL3 | c.593_599del p.R198Pfs*76 | Frame Shift Del (DEL) | VAF 21/54 reads (39%) | called by mutect2, pindel, varscan2
- RET | c.3109G>T p.E1037* | Nonsense Mutation (SNP) | VAF 24/179 reads (13%) | called by muse, mutect2, varscan2
- RNFT2 | c.881_882insT p.K294Nfs*31 | Frame Shift Ins (INS) | VAF 48/231 reads (21%) | called by mutect2, pindel, varscan2
- SASH1 | c.1282A>G p.M428V | Missense Mutation (SNP) | VAF 28/186 reads (15%) | SIFT tolerated (0.73); PolyPhen benign (0); called by muse, mutect2, varscan2
- SECISBP2 | c.2403del p.S802Afs*11 | Frame Shift Del (DEL) | VAF 107/449 reads (24%) | called by mutect2, pindel, varscan2
- SENP6 | c.176A>G p.D59G | Missense Mutation (SNP) | VAF 30/137 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.112); called by muse, mutect2, varscan2
- SFTPC | c.83G>A p.C28Y | Missense Mutation (SNP) | VAF 121/683 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- SIDT2 | c.985G>T p.V329L | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.67); PolyPhen benign (0.003); called by muse, mutect2
- SLC10A1 | c.608C>G p.T203R | Missense Mutation (SNP) | VAF 41/112 reads (37%) | SIFT tolerated (0.13); PolyPhen benign (0.201); called by muse, mutect2, varscan2
- SLC22A11 | c.1260G>T p.M420I | Missense Mutation (SNP) | VAF 50/281 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SLC25A53 | c.682G>T p.V228F | Missense Mutation (SNP) | VAF 63/340 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.121); called by muse, mutect2, varscan2
- SLC35G1 | c.737G>A p.G246E (on ENST00000427197 / NM_001134658.3; = p.G245E on NM_153226.4) | Missense Mutation (SNP) | VAF 20/100 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- SLC43A3 | c.674T>C p.L225P | Missense Mutation (SNP) | VAF 69/265 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- SLC5A5 | c.934C>A p.P312T | Missense Mutation (SNP) | VAF 201/734 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SLC6A5 | c.1995A>G p.I665M | Missense Mutation (SNP) | VAF 101/410 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- SLCO1B1 | c.1552T>C p.S518P | Missense Mutation (SNP) | VAF 115/471 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.71); called by muse, mutect2, varscan2
- SLCO1C1 | c.251T>G p.I84S | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- SMARCC2 | c.2272G>T p.E758* | Nonsense Mutation (SNP) | VAF 122/522 reads (23%) | called by muse, mutect2, varscan2
- SND1 | c.324G>T p.E108D | Missense Mutation (SNP) | VAF 22/210 reads (10%) | SIFT tolerated (0.29); PolyPhen benign (0.075); called by muse, mutect2, varscan2
- SORCS1 | c.1050G>T p.M350I | Missense Mutation (SNP) | VAF 19/184 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SPTB | c.4661A>G p.D1554G | Missense Mutation (SNP) | VAF 98/294 reads (33%) | SIFT tolerated (0.29); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- SSH3 | c.820G>T p.A274S | Missense Mutation (SNP) | VAF 52/451 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.102); called by muse, mutect2, varscan2
- STARD9 | c.10008G>T p.Q3336H | Missense Mutation (SNP) | VAF 40/204 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.222); called by muse, mutect2, varscan2
- STXBP5L | c.664G>A p.G222S | Missense Mutation (SNP) | VAF 27/214 reads (13%) | SIFT tolerated (0.63); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SV2A | c.1771G>T p.G591C | Missense Mutation (SNP) | VAF 169/625 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.454); called by muse, mutect2, varscan2
- TANC1 | c.695G>T p.S232I | Missense Mutation (SNP) | VAF 21/116 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- TCP11X2 | c.854C>G p.P285R | Missense Mutation (SNP) | VAF 167/881 reads (19%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.741); called by muse, mutect2, varscan2
- TERT | c.774C>G p.H258Q | Missense Mutation (SNP) | VAF 20/630 reads (3%) | SIFT tolerated (0.19); PolyPhen benign (0.396); called by muse, mutect2
- TG | c.6468C>G p.F2156L | Missense Mutation (SNP) | VAF 72/469 reads (15%) | SIFT tolerated (0.31); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- TICRR | c.2571A>T p.K857N | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.629); called by muse, mutect2, varscan2
- TJP1 | c.136A>C p.N46H | Missense Mutation (SNP) | VAF 17/128 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- TMCO5A | c.14G>C p.R5T | Missense Mutation (SNP) | VAF 25/94 reads (27%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.714); called by muse, mutect2, varscan2
- TP53TG5 | c.121del p.T41Rfs*3 | Frame Shift Del (DEL) | VAF 34/345 reads (10%) | called by mutect2, pindel, varscan2
- TPH1 | c.1258G>T p.A420S | Missense Mutation (SNP) | VAF 29/183 reads (16%) | SIFT tolerated (0.27); PolyPhen benign (0.376); called by muse, mutect2, varscan2
- TRAPPC11 | c.1825A>T p.I609F | Missense Mutation (SNP) | VAF 19/147 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.149); called by muse, mutect2, varscan2
- TRIM15 | c.502C>T p.Q168* | Nonsense Mutation (SNP) | VAF 51/179 reads (28%) | called by muse, mutect2, varscan2
- TRIM49 | c.478G>A p.V160M | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.001); called by mutect2, varscan2
- TRIM51GP | c.414G>C p.E138D | Missense Mutation (SNP) | VAF 19/139 reads (14%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.722); called by muse, mutect2, varscan2
- TRIM60 | c.1139C>T p.S380L | Missense Mutation (SNP) | VAF 26/139 reads (19%) | SIFT tolerated (0.83); PolyPhen benign (0.117); called by muse, varscan2
- TTLL7 | c.803A>G p.K268R | Missense Mutation (SNP) | VAF 67/266 reads (25%) | SIFT tolerated (0.3); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- TTN | c.74678G>A p.W24893* (on ENST00000591111; = p.W17469* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 142/369 reads (38%) | called by muse, mutect2, varscan2
- UCHL5 | c.664G>T p.A222S | Missense Mutation (SNP) | VAF 49/221 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.8); called by mutect2, varscan2
- UNC79 | c.4250G>T p.S1417I (on ENST00000393151 / NM_001346218.2; = p.S1240I on NM_020818.5) | Missense Mutation (SNP) | VAF 74/189 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- USH2A | c.9913G>T p.E3305* | Nonsense Mutation (SNP) | VAF 190/757 reads (25%) | called by muse, mutect2, varscan2
- USP30 | c.799G>T p.D267Y | Missense Mutation (SNP) | VAF 105/419 reads (25%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.808); called by muse, mutect2, varscan2
- UTRN | c.1820C>A p.S607Y | Missense Mutation (SNP) | VAF 18/167 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); called by muse, mutect2, varscan2
- VAT1L | c.333A>C p.E111D | Missense Mutation (SNP) | VAF 26/193 reads (13%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- VCAN | c.142dup p.T48Nfs*13 | Frame Shift Ins (INS) | VAF 96/282 reads (34%) | called by mutect2, pindel, varscan2
- VPS13C | c.2251G>T p.V751F (on ENST00000644861 / NM_020821.3; = p.V708F on NM_017684.5) | Missense Mutation (SNP) | VAF 14/112 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.387); called by muse, mutect2
- VRK2 | c.940A>T p.N314Y | Missense Mutation (SNP) | VAF 96/243 reads (40%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.65); called by muse, mutect2, varscan2
- VSX1 | c.1079G>C p.G360A | Missense Mutation (SNP) | VAF 58/584 reads (10%) | SIFT tolerated (0.38); PolyPhen benign (0.054); called by muse, mutect2
- ZER1 | c.977T>C p.L326P | Missense Mutation (SNP) | VAF 61/626 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.601); called by muse, mutect2
- ZFP57 | c.1278G>C p.R426S | Missense Mutation (SNP) | VAF 97/683 reads (14%) | SIFT tolerated (0.71); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- ZNF208 | c.3017G>T p.C1006F | Missense Mutation (SNP) | VAF 94/462 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZNF440 | c.749A>T p.H250L | Missense Mutation (SNP) | VAF 32/140 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF775 | c.578G>A p.C193Y | Missense Mutation (SNP) | VAF 179/490 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF80 | c.26G>C p.G9A | Missense Mutation (SNP) | VAF 20/85 reads (24%) | SIFT tolerated (0.05); PolyPhen benign (0.207); called by muse, mutect2, varscan2
- ZNHIT3 | c.211G>A p.D71N | Missense Mutation (SNP) | VAF 29/147 reads (20%) | SIFT tolerated (0.2); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ACTR5 | c.810G>A p.E270= | Silent (SNP) | VAF 38/262 reads (15%) | called by muse, mutect2, varscan2
- ADCY8 | c.3483G>A p.Q1161= | Silent (SNP) | VAF 40/355 reads (11%) | called by muse, mutect2, varscan2
- ADGB | c.2484C>A p.P828= | Silent (SNP) | VAF 11/79 reads (14%) | called by muse, mutect2, varscan2
- ADGRE2 | c.948G>T p.G316= | Silent (SNP) | VAF 79/291 reads (27%) | called by muse, mutect2, varscan2
- ADGRF5 | c.3243C>G p.L1081= | Silent (SNP) | VAF 27/182 reads (15%) | catalogued as rs778922968, COSV99345828; called by muse, mutect2, varscan2
- BCAS2 | c.561C>T p.S187= | Silent (SNP) | VAF 36/113 reads (32%) | called by muse, mutect2, varscan2
- BMPER | c.87C>T p.L29= | Silent (SNP) | VAF 177/973 reads (18%) | called by muse, mutect2, varscan2
- BPIFA1 | c.489C>A p.I163= | Silent (SNP) | VAF 21/364 reads (6%) | catalogued as COSV62824669; called by muse, mutect2
- BTBD10 | c.1104A>G p.R368= | Silent (SNP) | VAF 25/146 reads (17%) | called by muse, mutect2, varscan2
- CCDC136 | c.3021T>C p.S1007= | Silent (SNP) | VAF 33/108 reads (31%) | catalogued as rs1488095000; called by muse, mutect2, varscan2
- CCDC168 | c.18453C>A p.I6151= | Silent (SNP) | VAF 41/235 reads (17%) | called by muse, mutect2, varscan2
- CEP152 | c.3183C>T p.H1061= | Silent (SNP) | VAF 176/612 reads (29%) | called by muse, mutect2, varscan2
- CNTN1 | c.2949A>T p.G983= | Silent (SNP) | VAF 94/446 reads (21%) | called by muse, mutect2, varscan2
- COL15A1 | c.2148C>A p.V716= | Silent (SNP) | VAF 60/273 reads (22%) | called by muse, mutect2, varscan2
- COL1A2 | c.2922A>G p.K974= | Silent (SNP) | VAF 176/958 reads (18%) | catalogued as rs376325145; called by muse, mutect2, varscan2
- COL4A2 | c.1629C>A p.P543= | Silent (SNP) | VAF 68/533 reads (13%) | called by muse, mutect2, varscan2
- CPEB3 | c.399C>T p.T133= | Silent (SNP) | VAF 30/237 reads (13%) | catalogued as COSV56463163; called by muse, mutect2, varscan2
- CROCC2 | c.1206G>A p.L402= | Silent (SNP) | VAF 77/169 reads (46%) | called by muse, mutect2, varscan2
- CYFIP1 | c.1890G>A p.L630= | Silent (SNP) | VAF 35/275 reads (13%) | called by muse, mutect2, varscan2
- DDX55 | c.318G>A p.T106= | Silent (SNP) | VAF 136/514 reads (26%) | catalogued as rs140354761; called by muse, mutect2, varscan2
- DIP2B | c.4263C>T p.R1421= | Silent (SNP) | VAF 57/356 reads (16%) | called by muse, mutect2, varscan2
- DNAH5 | c.4281T>C p.N1427= | Silent (SNP) | VAF 45/200 reads (23%) | catalogued as rs1357709385; called by muse, mutect2, varscan2
- EEF1A2 | c.192G>A p.K64= | Silent (SNP) | VAF 46/322 reads (14%) | called by muse, mutect2, varscan2
- FAM187B | c.489G>T p.L163= | Silent (SNP) | VAF 70/258 reads (27%) | called by muse, mutect2, varscan2
- FFAR2 | c.156G>T p.T52= | Silent (SNP) | VAF 82/312 reads (26%) | called by mutect2, varscan2
- FRY | c.8916G>T p.L2972= | Silent (SNP) | VAF 66/455 reads (15%) | called by muse, mutect2, varscan2
- GCN1 | c.999G>T p.S333= | Silent (SNP) | VAF 67/388 reads (17%) | called by muse, mutect2, varscan2
- GDF7 | c.927G>A p.S309= | Silent (SNP) | VAF 70/653 reads (11%) | catalogued as rs778838756, COSV55347976; called by muse, mutect2, varscan2
- GEMIN4 | c.2985G>A p.P995= | Silent (SNP) | VAF 84/209 reads (40%) | catalogued as rs748658620, COSV56747953; called by muse, mutect2, varscan2
- GLB1L2 | c.30G>C p.P10= | Silent (SNP) | VAF 91/417 reads (22%) | called by muse, mutect2, varscan2
- GPR152 | c.1143G>A p.Q381= | Silent (SNP) | VAF 62/423 reads (15%) | called by muse, mutect2, varscan2
- GTPBP3 | c.283C>T p.L95= | Silent (SNP) | VAF 65/227 reads (29%) | called by muse, mutect2, varscan2
- HDAC9 | c.3207G>A p.L1069= (on ENST00000441542 / NM_178425.3; = p.L1066= on NM_178423.3) | Silent (SNP) | VAF 54/303 reads (18%) | called by muse, mutect2, varscan2
- HMCES | c.87C>T p.L29= | Silent (SNP) | VAF 98/454 reads (22%) | called by muse, mutect2, varscan2
- HMCN1 | c.2940G>A p.L980= | Silent (SNP) | VAF 31/444 reads (7%) | called by muse, mutect2
- HTR3A | c.1053C>A p.I351= | Silent (SNP) | VAF 51/194 reads (26%) | catalogued as COSV55467751; called by muse, mutect2, varscan2
- IGSF10 | c.3012C>A p.I1004= | Silent (SNP) | VAF 65/310 reads (21%) | called by muse, mutect2, varscan2
- JAG1 | c.261G>T p.T87= | Silent (SNP) | VAF 245/584 reads (42%) | called by muse, mutect2, varscan2
- JHY | c.1314C>T p.T438= | Silent (SNP) | VAF 57/241 reads (24%) | called by muse, mutect2, varscan2
- KAT14 | c.1365G>A p.P455= | Silent (SNP) | VAF 129/594 reads (22%) | catalogued as rs149391936; called by muse, mutect2, varscan2
- KDM5D | c.3756G>C p.L1252= | Silent (SNP) | VAF 71/155 reads (46%) | called by muse, mutect2, varscan2
- KIAA1755 | c.1743G>T p.L581= | Silent (SNP) | VAF 64/273 reads (23%) | catalogued as rs1372187473; called by muse, mutect2, varscan2
- KIF2B | c.1668G>T p.P556= | Silent (SNP) | VAF 52/266 reads (20%) | catalogued as rs902289645; called by muse, mutect2, varscan2
- KRT78 | c.1098G>T p.L366= | Silent (SNP) | VAF 89/384 reads (23%) | called by muse, mutect2, varscan2
- L1CAM | c.2106G>C p.P702= | Silent (SNP) | VAF 67/172 reads (39%) | catalogued as COSV62827812; called by muse, mutect2, varscan2
- LAIR2 | c.183G>A p.E61= | Silent (SNP) | VAF 77/416 reads (19%) | called by muse, mutect2, varscan2
- LEFTY2 | c.951C>T p.I317= | Silent (SNP) | VAF 115/878 reads (13%) | catalogued as rs376918921; called by muse, mutect2, varscan2
- LHX5 | c.1089C>A p.P363= | Silent (SNP) | VAF 112/380 reads (29%) | called by muse, mutect2, varscan2
- LINGO1 | c.294G>A p.E98= | Silent (SNP) | VAF 153/406 reads (38%) | catalogued as rs774339041; called by muse, mutect2, varscan2
- MDGA2 | c.663G>A p.E221= | Silent (SNP) | VAF 48/190 reads (25%) | called by muse, mutect2, varscan2
- MOGAT1 | c.195A>T p.P65= | Silent (SNP) | VAF 104/262 reads (40%) | called by muse, mutect2, varscan2
- MORC1 | c.1800G>A p.L600= | Silent (SNP) | VAF 51/190 reads (27%) | called by muse, mutect2, varscan2
- MOXD1 | c.567G>T p.L189= | Silent (SNP) | VAF 8/54 reads (15%) | called by muse, mutect2
- MTMR2 | c.615G>T p.G205= | Silent (SNP) | VAF 40/368 reads (11%) | called by muse, mutect2
- MYH15 | c.5400G>A p.Q1800= | Silent (SNP) | VAF 88/573 reads (15%) | called by muse, mutect2, varscan2
- MZB1 | c.339C>T p.L113= | Silent (SNP) | VAF 74/207 reads (36%) | called by muse, mutect2, varscan2
- NEIL3 | c.1713C>T p.N571= | Silent (SNP) | VAF 26/118 reads (22%) | called by muse, mutect2, varscan2
- NFKBIB | c.861C>A p.P287= | Silent (SNP) | VAF 99/381 reads (26%) | called by muse, mutect2, varscan2
- NIM1K | c.436C>T p.L146= | Silent (SNP) | VAF 20/722 reads (3%) | called by muse, mutect2
- NLRP7 | c.834G>C p.P278= | Silent (SNP) | VAF 118/504 reads (23%) | called by muse, mutect2, varscan2
- NOL4 | c.984G>A p.G328= | Silent (SNP) | VAF 47/304 reads (15%) | catalogued as rs532770554; called by muse, mutect2, varscan2
- OPTN | c.1026T>G p.S342= | Silent (SNP) | VAF 52/444 reads (12%) | called by muse, mutect2, varscan2
- OR14K1 | c.729C>T p.L243= | Silent (SNP) | VAF 64/255 reads (25%) | catalogued as rs760698783, COSV51720649; called by muse, mutect2, varscan2
- OR2T27 | c.186G>T p.L62= | Silent (SNP) | VAF 34/275 reads (12%) | called by muse, mutect2, varscan2
- OR2T34 | c.420G>C p.L140= | Silent (SNP) | VAF 31/149 reads (21%) | called by muse, mutect2, varscan2
- OR4C12 | c.504C>A p.G168= | Silent (SNP) | VAF 25/164 reads (15%) | called by muse, mutect2, varscan2
- OR5I1 | c.810A>G p.P270= | Silent (SNP) | VAF 18/128 reads (14%) | catalogued as COSV100041377; called by muse, mutect2, varscan2
- OR5M11 | c.186C>T p.F62= | Silent (SNP) | VAF 26/338 reads (8%) | catalogued as COSV101602012; called by muse, mutect2
- OR6N1 | c.144G>A p.V48= | Silent (SNP) | VAF 36/384 reads (9%) | catalogued as rs762892471, COSV100625138; called by muse, mutect2
- PCDHA8 | c.540A>G p.L180= | Silent (SNP) | VAF 118/291 reads (41%) | called by muse, mutect2, varscan2
- PCDHB9 | c.354G>T p.R118= | Silent (SNP) | VAF 52/188 reads (28%) | called by muse, mutect2, varscan2
- PKHD1L1 | c.6543C>A p.S2181= | Silent (SNP) | VAF 28/115 reads (24%) | called by muse, mutect2, varscan2
- PLCH1 | c.1248G>T p.L416= (on ENST00000340059 / NM_001130960.2; = p.L428= on NM_014996.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 78/461 reads (17%) | catalogued as COSV100395624; called by muse, mutect2, varscan2
- PLXNA4 | c.3168A>G p.T1056= | Silent (SNP) | VAF 81/241 reads (34%) | called by muse, mutect2, varscan2
- POLR3B | c.1332A>T p.S444= | Silent (SNP) | VAF 119/484 reads (25%) | catalogued as rs145020083; called by muse, mutect2, varscan2
- PRLHR | c.426G>T p.P142= | Silent (SNP) | VAF 39/247 reads (16%) | catalogued as COSV53305551; called by muse, mutect2, varscan2
- PRSS53 | c.729C>A p.I243= | Silent (SNP) | VAF 15/509 reads (3%) | called by muse, mutect2
- PTRH2 | c.123C>T p.P41= | Silent (SNP) | VAF 148/592 reads (25%) | called by muse, mutect2, varscan2
- RECQL4 | c.3171C>G p.G1057= | Silent (SNP) | VAF 38/237 reads (16%) | called by muse, mutect2, varscan2
- RHOBTB3 | c.375A>T p.S125= | Silent (SNP) | VAF 52/167 reads (31%) | called by muse, mutect2, varscan2
- SIDT2 | c.987G>T p.V329= | Silent (SNP) | VAF 6/30 reads (20%) | catalogued as rs753718397; called by muse, mutect2
- SLC43A3 | c.108C>T p.V36= | Silent (SNP) | VAF 36/285 reads (13%) | called by muse, mutect2, varscan2
- SLC7A14 | c.1809G>A p.L603= | Silent (SNP) | VAF 29/188 reads (15%) | called by muse, mutect2, varscan2
- SLCO1A2 | c.1584C>A p.A528= | Silent (SNP) | VAF 45/156 reads (29%) | called by muse, mutect2, varscan2
- SMARCA2 | c.2649G>A p.P883= | Silent (SNP) | VAF 286/602 reads (48%) | catalogued as rs773251995, COSV61806902; called by muse, mutect2, varscan2
- SOGA3 | c.645C>T p.S215= | Silent (SNP) | VAF 86/426 reads (20%) | called by muse, mutect2, varscan2
- SRRM2 | c.879G>T p.G293= | Silent (SNP) | VAF 114/480 reads (24%) | catalogued as COSV57068904; called by muse, mutect2, varscan2
- TEX50 | c.18A>G p.L6= | Silent (SNP) | VAF 20/89 reads (22%) | catalogued as rs1413304277; called by muse, mutect2, varscan2
- TIAM1 | c.96C>G p.L32= | Silent (SNP) | VAF 36/244 reads (15%) | called by muse, mutect2, varscan2
- TMEM255B | c.216T>A p.I72= | Silent (SNP) | VAF 48/292 reads (16%) | called by muse, mutect2, varscan2
- TNFSF13B | c.573T>A p.G191= | Silent (SNP) | VAF 15/150 reads (10%) | called by muse, mutect2
- TNN | c.3013C>T p.L1005= | Silent (SNP) | VAF 91/361 reads (25%) | called by muse, mutect2, varscan2
- TUBA3D | c.132C>A p.G44= | Silent (SNP) | VAF 238/526 reads (45%) | called by muse, mutect2, varscan2
- UBL5 | c.195G>A p.G65= | Silent (SNP) | VAF 19/183 reads (10%) | called by muse, mutect2, varscan2
- WBP4 | c.492A>G p.A164= | Silent (SNP) | VAF 38/156 reads (24%) | called by muse, mutect2, varscan2
- ZDHHC9 | c.690C>A p.L230= | Silent (SNP) | VAF 82/334 reads (25%) | called by muse, mutect2, varscan2
- ZNF436 | c.819G>T p.T273= | Silent (SNP) | VAF 98/227 reads (43%) | called by muse, mutect2, varscan2
- ZNF84 | c.912A>T p.S304= | Silent (SNP) | VAF 105/447 reads (23%) | called by muse, mutect2, varscan2
- AC008080.1 | n.489C>A | RNA (SNP) | VAF 68/282 reads (24%) | called by muse, mutect2, varscan2
- AC090151.1 | chr8:54701535 G>T | 3'Flank (SNP) | VAF 88/279 reads (32%) | called by muse, mutect2, varscan2
- AC093512.2 | c.*621+9A>T | Intron (SNP) | VAF 111/405 reads (27%) | called by muse, mutect2, varscan2
- AC099552.1 | n.262G>A | RNA (SNP) | VAF 84/332 reads (25%) | called by muse, mutect2
- ANKRD11 | c.227-540G>T | Intron (SNP) | VAF 83/472 reads (18%) | called by muse, mutect2, varscan2
- ANO1 | c.1950+26del | Intron (DEL) | VAF 80/474 reads (17%) | called by mutect2, pindel, varscan2
- ARL13B | c.*1469G>T | 3'UTR (SNP) | VAF 32/60 reads (53%) | called by muse, mutect2, varscan2
- BANP | c.339-755A>G | Intron (SNP) | VAF 30/160 reads (19%) | called by muse, mutect2, varscan2
- CDH13 | c.157+10G>C | Intron (SNP) | VAF 30/173 reads (17%) | called by muse, mutect2, varscan2
- CDHR2 | c.124+1260G>A | Intron (SNP) | VAF 67/186 reads (36%) | called by muse, mutect2, varscan2
- CEP41 | c.*3508T>C | 3'UTR (SNP) | VAF 14/376 reads (4%) | called by muse, mutect2
- CFAP47 | c.2844+16G>T | Intron (SNP) | VAF 50/128 reads (39%) | called by muse, mutect2, varscan2
- CHTF18 | c.607-83G>T | Intron (SNP) | VAF 45/259 reads (17%) | called by muse, mutect2, varscan2
- COL4A2 | c.648+12G>A | Intron (SNP) | VAF 83/508 reads (16%) | called by muse, mutect2, varscan2
- CYBA | c.204-40G>A | Intron (SNP) | VAF 92/398 reads (23%) | called by muse, mutect2, varscan2
- DLL3 | c.1093+99A>G | Intron (SNP) | VAF 12/40 reads (30%) | catalogued as rs1323422500; called by muse, mutect2
- EGFLAM | c.98-32028C>T | Intron (SNP) | VAF 37/234 reads (16%) | called by muse, mutect2, varscan2
- ERCC6 | c.4062+29G>C | Intron (SNP) | VAF 38/260 reads (15%) | called by muse, mutect2, varscan2
- ERN2 | c.306+989G>C | Intron (SNP) | VAF 57/292 reads (20%) | called by muse, mutect2, varscan2
- EYS | c.1767-7814A>T | Intron (SNP) | VAF 36/149 reads (24%) | called by mutect2, varscan2
- FILIP1L | c.605+25652G>A | Intron (SNP) | VAF 8/28 reads (29%) | called by muse, mutect2
- FKTN | c.*6T>A | 3'UTR (SNP) | VAF 56/247 reads (23%) | called by muse, mutect2, varscan2
- FMN2 | c.-197G>C | 5'UTR (SNP) | VAF 11/39 reads (28%) | called by muse, mutect2, varscan2
- FRMPD2 | c.2990-39A>T | Intron (SNP) | VAF 21/197 reads (11%) | called by muse, mutect2, varscan2
- FSHB | c.*45C>A | 3'UTR (SNP) | VAF 47/260 reads (18%) | catalogued as rs763739699; called by muse, mutect2, varscan2
- GALNS | c.-50G>C | 5'UTR (SNP) | VAF 83/377 reads (22%) | called by muse, mutect2, varscan2
- GBX1 | c.539-778G>T | Intron (SNP) | VAF 28/394 reads (7%) | called by muse, mutect2
- H3P12 | chr3:109410173 G>A | 5'Flank (SNP) | VAF 108/743 reads (15%) | catalogued as rs1233986727; called by muse, mutect2, varscan2
- IGFN1 | c.1242-327T>A | Intron (SNP) | VAF 110/503 reads (22%) | called by muse, mutect2, varscan2
- IL11 | c.*6G>A | 3'UTR (SNP) | VAF 167/626 reads (27%) | catalogued as rs749539580; called by muse, mutect2, varscan2
- JPT1 | c.57-439C>T | Intron (SNP) | VAF 43/170 reads (25%) | called by muse, mutect2, varscan2
- KARS1 | c.-19G>T | 5'UTR (SNP) | VAF 92/579 reads (16%) | called by muse, mutect2, varscan2
- KLHL14 | c.-44+556G>A | Intron (SNP) | VAF 33/155 reads (21%) | called by muse, mutect2, varscan2
- KLHL32 | c.-22A>T | 5'UTR (SNP) | VAF 34/181 reads (19%) | called by muse, mutect2, varscan2
- LINC00174 | n.3723C>A | RNA (SNP) | VAF 169/551 reads (31%) | called by muse, mutect2, varscan2
- LINC00452 | n.878G>T | RNA (SNP) | VAF 69/254 reads (27%) | called by muse, mutect2, varscan2
- LIX1 | c.483+2099T>A | Intron (SNP) | VAF 59/210 reads (28%) | called by muse, mutect2, varscan2
- MAGI2 | c.538+43639C>T | Intron (SNP) | VAF 4/34 reads (12%) | called by muse, mutect2
- MED25 | c.2146+62A>G | Intron (SNP) | VAF 118/511 reads (23%) | called by muse, mutect2, varscan2
- MRTFB | c.1079+268del | Intron (DEL) | VAF 12/95 reads (13%) | called by mutect2, pindel, varscan2
- MUC19 | n.23133C>T | RNA (SNP) | VAF 36/198 reads (18%) | called by muse, mutect2, varscan2
- MUC6 | c.3808+98A>T | Intron (SNP) | VAF 88/593 reads (15%) | called by muse, mutect2, varscan2
- MYPN | c.*581C>T | 3'UTR (SNP) | VAF 106/721 reads (15%) | catalogued as rs562141434; called by muse, mutect2, varscan2
- NCAM1 | c.-16del | 5'UTR (DEL) | VAF 45/186 reads (24%) | called by mutect2, pindel, varscan2
- NPIPA8 | chr16:18337406 C>A | 5'Flank (SNP) | VAF 25/237 reads (11%) | called by mutect2, varscan2
- OBSCN | c.11659+3618G>A | Intron (SNP) | VAF 98/423 reads (23%) | called by muse, mutect2, varscan2
- PEG10 | c.*240A>T | 3'UTR (SNP) | VAF 90/270 reads (33%) | called by muse, mutect2, varscan2
- RHOC | c.-532G>A | 5'UTR (SNP) | VAF 60/200 reads (30%) | called by muse, mutect2, varscan2
- SART1 | c.372-71T>A | Intron (SNP) | VAF 59/225 reads (26%) | called by muse, mutect2, varscan2
- SLC22A20P | n.546G>T | RNA (SNP) | VAF 122/527 reads (23%) | called by muse, mutect2, varscan2
- SLC25A37 | c.-14C>A | 5'UTR (SNP) | VAF 9/78 reads (12%) | catalogued as rs750111109; called by muse, mutect2
- SLC2A14 | c.88-7091G>T | Intron (SNP) | VAF 53/206 reads (26%) | catalogued as rs1285243805, COSV61587880; called by muse, mutect2, varscan2
- SLC9A8 | c.*11C>G | 3'UTR (SNP) | VAF 73/512 reads (14%) | called by muse, mutect2, varscan2
- SLC9B1P1 | n.675G>T | RNA (SNP) | VAF 33/97 reads (34%) | called by muse, mutect2, varscan2
- SLCO3A1 | c.181-26815A>T | Intron (SNP) | VAF 25/230 reads (11%) | called by muse, mutect2
- SMAP1 | c.339-63G>C | Intron (SNP) | VAF 20/130 reads (15%) | called by muse, mutect2
- SMARCA4 | c.4171-1813A>G | Intron (SNP) | VAF 35/185 reads (19%) | called by muse, mutect2, varscan2
- SSPOP | n.13454G>T | RNA (SNP) | VAF 159/507 reads (31%) | catalogued as rs1371120179; called by muse, mutect2, varscan2
- TBC1D3P1 | n.178C>A | RNA (SNP) | VAF 54/305 reads (18%) | called by mutect2, varscan2
- UBE3B | c.630+504C>T | Intron (SNP) | VAF 59/259 reads (23%) | called by muse, mutect2, varscan2
- ZC4H2 | c.399-29G>T | Intron (SNP) | VAF 17/68 reads (25%) | called by muse, mutect2, varscan2
